TCGA case TCGA-KK-A7B4 — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Prostate gland; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5447a0e0-80ca-40fb-8233-504fde51f22c

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 64 years; Vital status: Alive.

Diagnoses (3)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 64.7 years (23,644 days); Year of diagnosis: 2012; Method of diagnosis: Core Biopsy; AJCC clinical T: T3b; AJCC clinical M: M0; AJCC pathologic T: T3b; AJCC pathologic N: N1; Primary gleason grade: Pattern 4; Secondary gleason grade: Pattern 5; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Gleason score: 9.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 8; Lymph nodes tested: 20; Tumor level prostate: Apex / Middle / Base; Zone of origin prostate: Overlapping/multiple zones.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Leuprolide Acetate; Days to treatment start: 119 days; Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Bicalutamide; Days to treatment start: 312 days; Days to treatment end: 439 days (1.2 years); Treatment outcome: Stable Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Head, face or neck, NOS; Classification of tumor: Prior primary; Age at diagnosis: 52.1 years (19,025 days); Days to diagnosis: -4,619 days (-12.6 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: -4,588 days (-12.6 years); Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS; Surgery, NOS.
3. Recurrence of diagnosis 1 (Adenocarcinoma, NOS), site: Bone, NOS. Age at diagnosis: 67.4 years (24,607 days); Days to diagnosis: 963 days (2.6 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.

Follow-up (5 entries)
- Day 29 (initial diagnosis): Days to imaging: 29 days; Imaging type: Bone Scan, NOS; Imaging result: Indeterminate.
- Day 29 (initial diagnosis): Days to imaging: 29 days; Imaging type: MRI; Imaging findings: Equivocal.
- Day 637 (post initial treatment): Disease response: With Tumor; Progression or recurrence: Yes; Progression or recurrence type: Biochemical; Days to recurrence: 637 days (1.7 years).
- Day 963 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Bone, NOS; Days to recurrence: 963 days (2.6 years).
- Days to follow up: 987 days (2.7 years); Disease response: With Tumor.

Molecular and laboratory tests
- Prostate-Specific Antigen (PSA): 0.6 ng/mL (day 637).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-KK-A7B4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 160 mg.
  Slide TCGA-KK-A7B4-01A-01-TSA: Section location: Top; Percent tumor cells: 73; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 25; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-KK-A7B4-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-KK-A7B4-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 220 mg.
  Slide TCGA-KK-A7B4-11A-01-TSA: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 8; Percent necrosis: 0; Percent stromal cells: 92; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Zone of origin: Overlapping / Multiple Zones; Method initial path diagnosis: Core needle biopsy; Ct scan ab pelvis indicator: No; Diagnostic mri performed: Yes; Lymph nodes examined: Yes; Biochemical recurrence indicator: Yes.
- Tumor levels: Tumor level: Apex; Tumor level: Middle; Tumor level: Base.
- Stage record, Psa: PSA most recent results: 0.6.
- Stage record, Gleason grading: Gleason pattern primary: 4; Gleason pattern secondary: 5.
- Drug treatment 2: Pharmaceutical therapy drug name: Casodex.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease; New tumor event type: Locoregional Recurrence; New tumor event site: Bone; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; Progression after hormone treatment: Yes; Progression after hormone treatment type: Distant Metastasis.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Neck; Other malignancy histological type: Squamous Cell Carcinoma, Not Otherwise Specified.
- Other malignancy form, Radiation treatment: History radiation treatment to site of TCGA tumor: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 987 days; disease-specific survival: no event (censored), 987 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 637 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-KK-A7B4-01A-11D-A32A-01): tumor purity 0.72, ploidy 1.9, whole-genome doublings 0.
